Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13O, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13O-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

Papillary thyroid carcinoma.

Specimens Submitted:

- 1: SP: Thyroid, Total thyroidectomy
2: SP: Left paratracheal cyst

DIAGNOSIS:

1. SP: Thyroid, Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
with tall cell features

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type
Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Focal invasion

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

ICD-O-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9

[page 2 of 4]
Date of Procedure:

Date of Receipt:

Date of Report:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Papillary thyroid carcinoma.

Specimens Submitted:

1: SP: Thyroid, Total thyroidectomy

2: SP: Left paratracheal cyst

DIAGNOSIS:

1. SP: Thyroid, Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
with tall cell features

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type
Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Focal invasion

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

[page 3 of 4]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

- Two benign lymph nodes (0/2)

2. SP: Soft tissue, Left paratracheal cyst; Excision:

- Four benign lymph nodes
- Benign cyst lined by cuboidal epithelium most probably of branchial pouch derivation.
- Benign portion of thymus

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "total thyroidectomy stitch is right superior pole" and consists of a thyroid weighing 27 g. The right lobe measures 5 x 2.5 x 2.2 cm, the left lobe measures 4.5 x 2.5 x 2.2 cm and the isthmus measures 1.5 x 1.1 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.1 x 0.8 x 0.7 cm solid encapsulated calcified nodule in the right upper pole. Sections through the remaining tissue reveal no other lesions. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen is submitted for TPS. The remaining tissue is serially sectioned and 60% submitted.

Summary of sections:

N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

2). Specimen is received fresh labeled "left paratracheal cyst" and consists of an unoriented tan, soft tissue with dimensions of 2 x 2 by 1 cm. The external surface is inked black. Sectioning reveals a smooth walled cyst filled with clear watery fluid with a diameter of 1.5 cm. The specimen is entirely submitted.

Summary of sections:

U-undesigned

Summary of Sections:

Part 1: SP: Thyroid, Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
4	LL	4
2	N	2
4	RL	4

Part 2: SP: Left paratracheal cyst

Block	Sect. Site	PCs
2	U	2

[page 4 of 4]
last pay

Source: NCI Genomic Data Commons file e01d7265-9c03-442e-b8bf-99f6e7fb66c9 (TCGA-DJ-A13O.607A9AB4-E9E6-434A-AF81-C11035C93174.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).